MMRF case MMRF_1845 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/c890ba71-335c-48d6-a184-abf26948eef2

Demographics
Sex at birth: female; Race: asian; Ethnicity: not hispanic or latino; Age at index: 46 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 46.6 years (17,031 days); ISS stage: III; Days to last known disease status: 1,065 days (2.9 years); Days to last follow up: 1,065 days (2.9 years).
   Treatment given: Therapeutic agents: Bortezomib + Cyclophosphamide + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 56 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 145 days; Days to treatment end: 170 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 145 days; Days to treatment end: 198 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 171 days; Days to treatment end: 198 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 200 days; Days to treatment end: 200 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 201 days; Days to treatment end: 201 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -13 (ECOG 0): M Protein 3.77 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.51 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 143 mg/dL; Immunoglobulin G 54.5 g/L; Immunoglobulin A 0.3 g/L; Immunoglobulin M 0.2 g/L; Beta 2 Microglobulin 5.6 µg/mL; Lactate Dehydrogenase 2.95 µkat/L; Hemoglobin 6.51 mmol/L; Leukocytes 9.2 ×10⁹/L; Absolute Neutrophil 5.3 ×10⁹/L; Platelets 340 ×10⁹/L; Creatinine 70 µmol/L; Calcium 2.43 mmol/L; Albumin 37 g/L; Total Protein 10.9 g/dL; Glucose 6.3 mmol/L; C-Reactive Protein 0.3 mg/dL.
- Day 85 (ECOG 1): M Protein 5.6 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.46 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.77 mg/dL; Immunoglobulin G 12.9 g/L; Immunoglobulin A 0.42 g/L; Immunoglobulin M 0.25 g/L; Hemoglobin 6.26 mmol/L; Leukocytes 8.3 ×10⁹/L; Absolute Neutrophil 3.5 ×10⁹/L; Platelets 395 ×10⁹/L; Creatinine 53 µmol/L; Calcium 2.32 mmol/L; Albumin 32 g/L; Total Protein 6.4 g/dL; Glucose 8.7 mmol/L.
- Day 162 (ECOG 1): M Protein 1.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.21 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.82 mg/dL; Immunoglobulin G 9.3 g/L; Immunoglobulin A 0.86 g/L; Immunoglobulin M 0.4 g/L; Lactate Dehydrogenase 3.95 µkat/L; Hemoglobin 7.56 mmol/L; Leukocytes 8.3 ×10⁹/L; Absolute Neutrophil 5.5 ×10⁹/L; Platelets 301 ×10⁹/L; Creatinine 62 µmol/L; Calcium 2.47 mmol/L; Albumin 40 g/L; Total Protein 7 g/dL; Glucose 14.8 mmol/L.
- Day 246 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.84 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.99 mg/dL; Immunoglobulin G 10.9 g/L; Immunoglobulin A 1.26 g/L; Immunoglobulin M 0.39 g/L; Hemoglobin 6.94 mmol/L; Leukocytes 9.1 ×10⁹/L; Absolute Neutrophil 3.57 ×10⁹/L; Platelets 298 ×10⁹/L; Creatinine 59 µmol/L; Calcium 2.54 mmol/L; Albumin 39 g/L; Total Protein 7.3 g/dL; Glucose 8.8 mmol/L.
- Day 358 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.63 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.55 mg/dL; Immunoglobulin G 11 g/L; Immunoglobulin A 1.56 g/L; Immunoglobulin M 0.49 g/L; Hemoglobin 7.07 mmol/L; Leukocytes 10 ×10⁹/L; Absolute Neutrophil 6.5 ×10⁹/L; Platelets 207 ×10⁹/L; Creatinine 68 µmol/L; Calcium 2.5 mmol/L; Albumin 44 g/L; Total Protein 7.7 g/dL; Glucose 8.1 mmol/L.
- Day 428 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.95 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.31 mg/dL; Immunoglobulin G 11 g/L; Immunoglobulin A 1.76 g/L; Immunoglobulin M 0.4 g/L; Hemoglobin 7.19 mmol/L; Leukocytes 9.8 ×10⁹/L; Absolute Neutrophil 4 ×10⁹/L; Platelets 281 ×10⁹/L; Creatinine 67 µmol/L; Calcium 2.4 mmol/L; Albumin 42 g/L; Total Protein 7.4 g/dL; Glucose 7.3 mmol/L.
- Day 568 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.14 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.58 mg/dL; Immunoglobulin G 12 g/L; Immunoglobulin A 2.55 g/L; Immunoglobulin M 0.53 g/L; Hemoglobin 7.69 mmol/L; Leukocytes 13.3 ×10⁹/L; Absolute Neutrophil 7.9 ×10⁹/L; Platelets 321 ×10⁹/L; Creatinine 89 µmol/L; Calcium 2.5 mmol/L; Albumin 43 g/L; Total Protein 8.2 g/dL; Glucose 8.5 mmol/L.
- Day 652 (ECOG 0): M Protein 1.6 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.83 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 5.84 mg/dL; Immunoglobulin G 11.8 g/L; Immunoglobulin A 2.41 g/L; Immunoglobulin M 0.46 g/L; Hemoglobin 7.56 mmol/L; Leukocytes 11.2 ×10⁹/L; Absolute Neutrophil 5.8 ×10⁹/L; Platelets 337 ×10⁹/L; Creatinine 92 µmol/L; Calcium 2.6 mmol/L; Albumin 46 g/L; Total Protein 8.3 g/dL; Glucose 7.1 mmol/L.
- Day 750 (ECOG 0): M Protein 2.9 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.8 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 11.1 mg/dL; Immunoglobulin G 13 g/L; Immunoglobulin A 2.5 g/L; Immunoglobulin M 0.45 g/L; Hemoglobin 7.38 mmol/L; Leukocytes 11.5 ×10⁹/L; Absolute Neutrophil 5.7 ×10⁹/L; Platelets 354 ×10⁹/L; Creatinine 115 µmol/L; Calcium 2.53 mmol/L; Albumin 46 g/L; Total Protein 8 g/dL; Glucose 9.5 mmol/L.
- Day 792: M Protein 3.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.94 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 9.88 mg/dL; Immunoglobulin G 13.2 g/L; Immunoglobulin A 2.73 g/L; Immunoglobulin M 0.39 g/L; Lactate Dehydrogenase 2.37 µkat/L; Hemoglobin 7.19 mmol/L; Leukocytes 13.9 ×10⁹/L; Absolute Neutrophil 8.26 ×10⁹/L; Platelets 432 ×10⁹/L; Creatinine 101 µmol/L; Calcium 2.5 mmol/L; Albumin 46 g/L; Total Protein 8.1 g/dL; Glucose 10.4 mmol/L.
- Day 897 (ECOG 0): M Protein 3.6 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.18 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 21.3 mg/dL; Immunoglobulin G 12.7 g/L; Immunoglobulin A 2.19 g/L; Immunoglobulin M 0.29 g/L; Hemoglobin 7.07 mmol/L; Leukocytes 8.8 ×10⁹/L; Absolute Neutrophil 4.8 ×10⁹/L; Platelets 342 ×10⁹/L; Creatinine 73 µmol/L; Calcium 2.41 mmol/L; Albumin 41 g/L; Total Protein 7.1 g/dL; Glucose 12.3 mmol/L.
- Day 981 (ECOG 1): M Protein 5.9 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.31 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 22.3 mg/dL; Immunoglobulin G 14.4 g/L; Immunoglobulin A 2.74 g/L; Immunoglobulin M 0.3 g/L; Hemoglobin 7.44 mmol/L; Leukocytes 13.8 ×10⁹/L; Absolute Neutrophil 10 ×10⁹/L; Platelets 343 ×10⁹/L; Creatinine 78 µmol/L; Calcium 2.55 mmol/L; Albumin 43 g/L; Total Protein 8 g/dL; Glucose 10.3 mmol/L.
- Day 1,065: M Protein 9.6 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.63 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 47.8 mg/dL; Immunoglobulin G 20.5 g/L; Immunoglobulin A 2.15 g/L; Immunoglobulin M 0.45 g/L; Hemoglobin 7.5 mmol/L; Leukocytes 8.8 ×10⁹/L; Absolute Neutrophil 4.3 ×10⁹/L; Platelets 398 ×10⁹/L; Creatinine 73 µmol/L; Calcium 2.54 mmol/L; Albumin 43 g/L; Total Protein 8.6 g/dL; Glucose 8.6 mmol/L.

Other clinical attributes
- Day -13: Weight: 56 kg; Height: 153 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_1845_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -13 days.
- Sample MMRF_1845_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -13 days.
